Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A285, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A285-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Ascending Colon			
Date of Cancer Sample Procurement:				
Histology:	Adenocarcinoma			
Description of other histology:				
Grade:	Moderately Differentiated			
Mucinous:	☐ No	☐ Yes	☒ Yes (Focal)	☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal)	☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown	
Host Response:	None			
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown	
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown	
Growth Pattern:	☐ Expansile	☒ Invasive	☐ Expansile and Invasive	☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown	
Angiolymphatic Invasion:	☐ No	☒ Yes	☐ Unknown	
Mutator Phenotype:	☒ No	☐ Yes	☐ Unknown	
Number of Slides	1			
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal)	☐ Unknown
TIL Cells / HPF	1			
Pathologist Comment:				

ICD-0-3
adenocarcinoma, mucinoma, NOS 8480/3
Site: ascending colon C18.2
for 5/3/11

Dual/Syr - thoracic Primary Noted		

Source: NCI Genomic Data Commons file 5f40c5c0-c7c4-4887-8f99-7b4d576e4deb (TCGA-DM-A285.1B9E9C45-C8A3-4CFA-AB47-965056517D4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).